Gene-level copy-number profile of specimen HCM-CSHL-0857-C19-85M from HCMI case HCM-CSHL-0857-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,244 days).
Specimen HCM-CSHL-0857-C19-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 282226a4-98fc-43ee-b990-15b1c3d83c62.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0857-C19-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/485d72e4-8e4d-4adc-ae41-2911ee946c19

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 504; copy number 1: 1,529; copy number 2: 12,371; copy number 3: 31,166; copy number 4: 8,710; copy number 5: 3,173; copy number 6: 1,369; copy number 7: 12; copy number 11: 18; copy number 13: 34; copy number 14: 8; copy number 17: 5; copy number 19: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 84 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:137,682–195,411, 8 genes, copy number 11: AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr9:65,189,995–65,230,861, 3 genes, copy number 7: BMS1P12, AL512605.1, AL512605.2.
- chr11:7,222,933–7,469,043, 3 genes, copy number 7 (within-gene range 6–7): AC027804.1, MIR302E, SYT9.
- chr11:10,797,050–10,808,940, 2 genes, copy number 7: EIF4G2, SNORD97.
- chr11:18,322,295–18,367,045, 1 gene, copy number 7: GTF2H1.
- chr11:76,186,325–78,582,156, 67 genes, copy number 7–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,529. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
